MMRF case MMRF_2404 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8eab3a6b-11f6-4819-a19a-1faeb8e1c52d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Dead; Days to death: 331 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.1 years (18,306 days); ISS stage: III; Days to last known disease status: 331 days; Days to last follow up: 331 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 33 days; Days to treatment end: 202 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 103 days; Days to treatment end: 103 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 104 days; Days to treatment end: 104 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 207 days; Days to treatment end: 245 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 331.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 4.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 172 mg/dL; Immunoglobulin G 5.7 g/L; Immunoglobulin A 42.9 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 15.3 µg/mL; Hemoglobin 5.39 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 131 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 10 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 3.73 mg/dL.
- Day 81 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.762 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.2 mg/dL; Immunoglobulin G 5.1 g/L; Immunoglobulin A 10 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 5.85 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 22.7 ×10⁹/L; Absolute Neutrophil 17.5 ×10⁹/L; Platelets 346 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.03 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 162 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Immunoglobulin G 9.65 g/L; Immunoglobulin A 2.71 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.98 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 9.7 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L.
- Day 245 (ECOG 0): M Protein 2.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 419 mg/dL; Immunoglobulin G 6.82 g/L; Immunoglobulin A 24.5 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 4.47 µg/mL; Lactate Dehydrogenase 14.6 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.59 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 431 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 31 g/L; Total Protein 7.7 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day 1: Weight: 123 kg; Height: 177 cm.

Biospecimens (2 samples)
- Sample MMRF_2404_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2404_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
